Somatic mutation profile of tumor specimen TARGET-30-PAMYCE-01A (aliquot TARGET-30-PAMYCE-01A-01W) from TARGET case TARGET-30-PAMYCE, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.9 years (1,059 days).
Specimen TARGET-30-PAMYCE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 343c2059-c117-45a7-9e10-edd6b8093cdf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAMYCE-10A (Blood Derived Normal), aliquot TARGET-30-PAMYCE-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/177eabe6-2078-41f5-a322-b39b85633198

The open-access MAF lists 29 somatic variants for this specimen: 17 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 9, RNA 3, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACBD5 | c.1165G>A p.G389R (on ENST00000375888 / NM_001352568.1; = p.G380R on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 111/309 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201980004; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C15orf39 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV62297359; called by muse, mutect2, varscan2
- DSP | c.7833C>A p.D2611E | Missense Mutation (SNP) | VAF 76/200 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV65794005; called by muse, mutect2, varscan2
- ESPL1 | c.4031C>T p.P1344L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57760950; called by muse, mutect2, varscan2
- EXOC3 | c.576G>T p.W192C | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1405493068; called by muse, mutect2
- FCRL2 | c.281C>T p.T94I | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs1178375764, COSV63834325; called by muse, mutect2, varscan2
- FCRL6 | c.814G>T p.G272W | Missense Mutation (SNP) | VAF 100/338 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100220333, COSV58941869; called by muse, mutect2, varscan2
- FLG | c.3900G>T p.E1300D | Missense Mutation (SNP) | VAF 79/211 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.187); catalogued as COSV64244736; called by muse, mutect2, varscan2
- INSL6 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 22/828 reads (3%) | catalogued as COSV67562571, COSV67563158; called by muse, mutect2
- OPRM1 | c.1006G>T p.V336F | Missense Mutation (SNP) | VAF 209/513 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV57680609; called by muse, mutect2, varscan2
- OR5M10 | c.249C>A p.H83Q | Missense Mutation (SNP) | VAF 81/267 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as COSV73242377; called by muse, mutect2, varscan2
- OVCH1 | c.1418G>C p.C473S | Missense Mutation (SNP) | VAF 294/808 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV58965504; called by muse, mutect2, varscan2
- SLC25A48 | c.385A>G p.I129V | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.607); catalogued as rs774987757, COSV50849884; called by muse, mutect2, varscan2
- TCHH | c.5395G>T p.E1799* | Nonsense Mutation (SNP) | VAF 33/648 reads (5%) | catalogued as rs1314080059; called by muse, mutect2
- ZNF595 | c.41C>G p.S14C | Missense Mutation (SNP) | VAF 36/436 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1444470401, COSV100227863, COSV59547875; called by muse, mutect2
- GOLPH3 | c.864del p.L289Cfs*37 | Frame Shift Del (DEL) | VAF 117/391 reads (30%) | called by mutect2, pindel, varscan2
- PRUNE2 | c.7087G>C p.E2363Q | Missense Mutation (SNP) | VAF 16/428 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2
- CCDC112 | c.1080A>G p.E360= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV65473576; called by muse, mutect2, varscan2
- CCDC116 | c.675G>A p.L225= | Silent (SNP) | VAF 10/276 reads (4%) | catalogued as COSV53037857, COSV99488967; called by muse, mutect2
- GABRG1 | c.529C>T p.L177= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV54957834; called by muse, varscan2
- NEIL3 | c.541C>T p.L181= | Silent (SNP) | VAF 20/395 reads (5%) | called by muse, mutect2
- NOMO2 | c.2082G>A p.L694= | Silent (SNP) | VAF 10/40 reads (25%) | called by mutect2, varscan2
- PIPOX | c.711T>C p.Y237= | Silent (SNP) | VAF 25/702 reads (4%) | called by muse, mutect2
- PLOD1 | c.1875G>A p.E625= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV52147508; called by muse, mutect2, varscan2
- TRIM58 | c.192C>T p.F64= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV63571376; called by muse, varscan2
- TRO | c.642G>A p.K214= | Silent (SNP) | VAF 6/99 reads (6%) | called by muse, mutect2
- CCDC140 | n.768C>T | RNA (SNP) | VAF 23/71 reads (32%) | catalogued as COSV54674694; called by muse, mutect2, varscan2
- MIR1302-7 | n.37A>T | RNA (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- XIST | n.9132G>T | RNA (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
